Somatic mutation profile of tumor specimen TCGA-75-6206-01A (aliquot TCGA-75-6206-01A-11D-1753-08) from TCGA case TCGA-75-6206, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-75-6206-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bba1178-a1a8-4f9e-9ef3-ad41003065f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-6206-10A (Blood Derived Normal), aliquot TCGA-75-6206-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ce62e4b-ba0b-4410-a508-569d44de1f4b

The open-access MAF lists 93 somatic variants for this specimen: 75 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 67, Silent 18, Nonsense Mutation 7, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.1861C>A p.P621T (on ENST00000341947 / NM_080680.3; = p.P514T on NM_080679.2) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as rs121912952, CM053813, COSV59500310; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACP5 | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); catalogued as rs931778512, COSV54537019; called by muse, mutect2, varscan2
- ACTC1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV51760516; called by muse, mutect2, varscan2
- ADAM19 | c.2489C>A p.S830* | Nonsense Mutation (SNP) | VAF 26/130 reads (20%) | catalogued as rs35242691, COSV57433616, COSV57435619; called by muse, mutect2, varscan2
- ADGRL2 | c.4282G>T p.G1428C (on ENST00000370717 / NM_001366005.1; = p.G1372C on NM_012302.4) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54679940; called by muse, mutect2, varscan2
- ADORA2B | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753626617, COSV100419958; called by muse, mutect2, varscan2
- AP5M1 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1433395511, COSV99841004; called by muse, mutect2, varscan2
- APOA5 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1038704562, COSV57064219; called by muse, mutect2, varscan2
- APOBEC3G | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV68470029; called by muse, mutect2, varscan2
- ARHGAP35 | c.2503C>G p.L835V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as COSV68334048; called by muse, mutect2, varscan2
- CA9 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 103/214 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.207); catalogued as rs1183013228, COSV61407133; called by muse, mutect2, varscan2
- CAPN5 | c.908G>T p.R303L (on ENST00000456580; = p.R263L on NM_004055.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV99581688; called by muse, mutect2, varscan2
- CCDC107 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV58397783; called by muse, mutect2, varscan2
- CCDC191 | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV55674805; called by muse, mutect2, varscan2
- CHST6 | c.464G>C p.R155P | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV100178226; called by muse, mutect2, varscan2
- COL11A1 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62175429; called by muse, mutect2, varscan2
- COL11A1 | c.1323A>T p.E441D | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV62190918; called by muse, mutect2, varscan2
- CSMD1 | c.4996G>T p.G1666* (on ENST00000520002; = p.G1665* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 9/12 reads (75%) | catalogued as COSV59293452, COSV59315140; called by muse, mutect2, varscan2
- CSMD3 | c.2932A>T p.S978C (on ENST00000297405 / NM_001363185.1; = p.S874C on NM_052900.3) | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52263516; called by muse, mutect2, varscan2
- DCAF13 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV52573412; called by muse, mutect2, varscan2
- DCC | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59119273; called by muse, mutect2, varscan2
- EIF4G3 | c.3721G>T p.E1241* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as COSV51689350; called by muse, mutect2, varscan2
- ERICH3 | c.3760C>A p.L1254M | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV58613762; called by muse, mutect2, varscan2
- EXOSC9 | c.151G>T p.G51* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV54667320; called by muse, mutect2, varscan2
- FBH1 | c.279G>T p.M93I (on ENST00000362091 / NM_178150.3; = p.M144I on NM_032807.4) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV62983840; called by muse, mutect2, varscan2
- ICE1 | c.3871A>G p.N1291D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV56829423; called by muse, mutect2, varscan2
- KCNH1 | c.103G>C p.A35P | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165808410, COSV55094350, COSV99659737; called by muse, mutect2, varscan2
- KEAP1 | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50653005, COSV99407300; called by muse, mutect2, varscan2
- KRT36 | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV60204253; called by muse, mutect2
- LIPF | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53285533; called by muse, mutect2, varscan2
- LRP1B | c.2987G>T p.G996V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV67254385; called by muse, mutect2, varscan2
- MAN2A2 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs779403878, COSV64638428; called by muse, mutect2, varscan2
- MARCHF6 | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 104/200 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV56884657; called by muse, mutect2, varscan2
- MBD1 | c.1361C>G p.T454S (on ENST00000269468 / NM_001323950.1; = p.T398S on NM_002384.2) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.993); catalogued as COSV54004882; called by muse, mutect2, varscan2
- MYO9B | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 43/74 reads (58%) | catalogued as COSV101261221; called by muse, varscan2
- MYO9B | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV101261223; called by muse, varscan2
- NETO1 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100198155; called by muse, mutect2, varscan2
- NLRP3 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60229145; called by muse, mutect2, varscan2
- NT5C1B | c.1261G>A p.A421T (on ENST00000359846 / NM_001199086.2; = p.A361T on NM_033253.4) | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as COSV58397870; called by muse, mutect2, varscan2
- NUAK1 | c.1697G>T p.S566I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV54606301; called by muse, mutect2, varscan2
- OR2W3 | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV64457626; called by muse, mutect2
- OR51D1 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs774635180, COSV62913849, COSV62914620; called by muse, mutect2, varscan2
- PCDH9 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.733); catalogued as COSV100122233, COSV60574891; called by muse, mutect2
- PCDHA6 | c.662A>T p.E221V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV100972052, COSV65355375; called by muse, varscan2
- PDE6G | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58507914; called by muse, mutect2, varscan2
- PITPNM2 | c.1451A>T p.D484V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs140191385, COSV54905385; called by muse, mutect2, varscan2
- RBM28 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761737836, COSV56164137; called by muse, mutect2, varscan2
- RD3 | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as COSV100879187, COSV65361821; called by muse, mutect2, varscan2
- RTL3 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); catalogued as COSV58185113; called by muse, mutect2, varscan2
- SCN4A | c.5234G>T p.R1745L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs376526108, COSV71127030; called by muse, mutect2, varscan2
- SLC12A2 | c.2293C>G p.L765V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as rs548545596, COSV52474518; called by muse, mutect2, varscan2
- SLC35G5 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.159); catalogued as rs1382155619, COSV55314412; called by muse, mutect2, varscan2
- SLC9C2 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV62946320, COSV62947742; called by muse, mutect2, varscan2
- SOAT1 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62656002; called by muse, mutect2, varscan2
- SPEN | c.1284G>T p.R428S | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65362431; called by muse, mutect2, varscan2
- SYNE2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs759889097, COSV58362085; called by muse, mutect2, varscan2
- SYT4 | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54902785; called by muse, mutect2, varscan2
- TCP11 | c.1489G>T p.E497* (on ENST00000512012; = p.E435* on NM_018679.5) | Nonsense Mutation (SNP) | VAF 61/160 reads (38%) | catalogued as COSV55135194; called by muse, mutect2, varscan2
- TENM3 | c.4738C>A p.P1580T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.431); catalogued as COSV101304847; called by muse, mutect2, varscan2
- TENM3 | c.4739C>A p.P1580H | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV101304848; called by muse, mutect2, varscan2
- TIMD4 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV50854184, COSV99192480; called by muse, mutect2, varscan2
- TIMD4 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1306063086, COSV50854659; called by muse, mutect2, varscan2
- TMEM132B | c.2309A>G p.Q770R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV54745691, COSV54763144; called by muse, mutect2, varscan2
- TMEM43 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV55500158; called by muse, mutect2, varscan2
- UBTF | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57187649; called by muse, mutect2
- UGT2A2 | c.391A>T p.N131Y | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); catalogued as COSV99683798; called by muse, mutect2, varscan2
- UGT3A1 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV57101100; called by muse, mutect2, varscan2
- UNC13A | c.2924G>A p.S975N | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53204623; called by muse, mutect2, varscan2
- USP39 | c.1142A>C p.E381A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV60382770; called by muse, mutect2, varscan2
- VPS13B | c.1326C>G p.F442L | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1366082378, COSV62023544; called by muse, mutect2, varscan2
- ZNF28 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 71/288 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100354236; called by muse, mutect2, varscan2
- ZNF507 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV61332615; called by muse, mutect2, varscan2
- NPY5R | c.1082dup p.R362Efs*19 | Frame Shift Ins (INS) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- WWC2 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2
- GFM2 | c.1356C>G p.S452= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV57192523; called by muse, mutect2, varscan2
- HTR5A | c.990C>T p.N330= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV55285807; called by muse, mutect2, varscan2
- IGLJ7 | c.46G>T p.*16= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- IQGAP2 | c.3864A>T p.I1288= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV57178250; called by muse, mutect2, varscan2
- MGAT4C | c.816G>A p.L272= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV59835770; called by muse, mutect2, varscan2
- NCAM1 | c.1860G>A p.Q620= (on ENST00000316851 / NM_181351.5; = p.Q610= on NM_000615.7) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100376965; called by muse, mutect2, varscan2
- NPAP1 | c.3066C>T p.F1022= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs542087793, COSV100274736, COSV61511429; called by muse, varscan2
- OR5J2 | c.819G>A p.V273= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100398935, COSV56622563; called by muse, mutect2, varscan2
- PLXNA2 | c.2415A>T p.A805= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV65443085; called by muse, mutect2
- POSTN | c.1512A>G p.K504= | Silent (SNP) | VAF 118/168 reads (70%) | catalogued as COSV65713971; called by muse, mutect2, varscan2
- PRRC2C | c.1359A>G p.Q453= (on ENST00000367742; = p.Q451= on NM_015172.4) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV58910060, COSV58913595; called by muse, mutect2, varscan2
- RYR2 | c.7953C>T p.A2651= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2
- RYR3 | c.11421C>T p.V3807= (on ENST00000389232; = p.V3808= on NM_001036.6) | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV66802521; called by muse, mutect2, varscan2
- TSTD2 | c.546C>T p.P182= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV57847102; called by muse, mutect2, varscan2
- XPO7 | c.1482A>G p.T494= | Silent (SNP) | VAF 134/217 reads (62%) | catalogued as rs1369270176, COSV53018128; called by muse, mutect2, varscan2
- ZNF45 | c.412T>C p.L138= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs1407424527, COSV54194129; called by muse, mutect2, varscan2
- ZNF646 | c.303C>T p.G101= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV56217385; called by muse, mutect2, varscan2
- ZNF658 | c.2430G>A p.K810= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs939451155; called by muse, mutect2, varscan2
